CCDI case PBBVME — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b30e315e-2c67-4062-8bae-db2fe7e84022

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,304 days).

Biospecimens (3 samples)
- Sample 0DIYS4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIYSA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIYSG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
